Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46G, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46G-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: PART 1: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TEN (10) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SEVEN (7) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8 WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- B. PROMINENT DUCTAL DIFFERENTIATION IS IDENTIFIED.
- C. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM.
- D. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- F. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE ANTERIOR LEFT BASE REGION (SLIDE 3X), POSTERIOR LEFT APEX REGION (SLIDES 3EE AND 3FF) AND POSTERIOR LEFT MID REGION (SLIDE 3GG).
- G. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- M. TNM HISTOLOGIC GRADE = G4.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
Ductal adenocarcinoma
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 80%
WEIGHT OF PROSTATE: 57.9gm
TUMOR SIZE: Maximum dimension: 1.3 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 17
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-0-3

adenocarcinoma, duct, nos 8520/3
Site: prostate, nos C61.9

ju
7/27/12

Source: NCI Genomic Data Commons file f13a8c57-6f64-41ee-8ad9-4670fafa22f0 (TCGA-EJ-A46G.ACBA1CE1-E248-47D3-B03D-BE0C1B4A6F21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).